Somatic mutation profile of tumor specimen BLGSP-71-08-00043-01A (aliquot BLGSP-71-08-00043-01A-01D-A663-33) from CGCI case BLGSP-71-08-00043, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 4.6 years (1,667 days).
Specimen BLGSP-71-08-00043-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Cervical; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3ac403b-8f9e-4e10-baf9-5cd7a22955c9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00043-10A (Blood Derived Normal), aliquot BLGSP-71-08-00043-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/081a9579-9d36-4997-b9e7-1cb4263d77f6

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, 5'Flank 3, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 53/104 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218643327, COSV60787034; called by muse, mutect2, varscan2
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 72/187 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, varscan2
- H1-2 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs374082368, COSV59189744; called by muse, mutect2, varscan2
- ID3 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV65800799, COSV65801289; called by muse, varscan2
- NRG3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1240938401; called by muse, mutect2, varscan2
- SIN3A | c.3196-1G>A p.X1066_splice | Splice Site (SNP) | VAF 128/304 reads (42%) | catalogued as COSV64583232; called by muse, mutect2, varscan2
- XIRP2 | c.5066T>A p.I1689K (on ENST00000628543; = p.I1864K on NM_152381.6) | Missense Mutation (SNP) | VAF 124/257 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1287426209; called by muse, mutect2, varscan2
- ADAMTS20 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCBP1 | c.508del p.L170Sfs*10 | Frame Shift Del (DEL) | VAF 44/107 reads (41%) | called by mutect2, pindel, varscan2
- TCL1A | c.184A>G p.M62V | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCL7A | chr12:122021449 A>G | 5'Flank (SNP) | VAF 74/148 reads (50%) | catalogued as COSV104379276, COSV55850504; called by muse, varscan2
- CXCR4 | c.15+431G>A | Intron (SNP) | VAF 43/273 reads (16%) | called by muse, varscan2
- CXCR4 | c.15+350G>A | Intron (SNP) | VAF 110/224 reads (49%) | catalogued as rs867626998; called by muse, varscan2
- CXCR4 | c.15+329G>C | Intron (SNP) | VAF 98/207 reads (47%) | catalogued as rs1244191764, COSV54012733, COSV54014652; called by muse, varscan2
- ID3 | c.*26-208A>T | Intron (SNP) | VAF 104/245 reads (42%) | called by muse, mutect2, varscan2
- MYC | chr8:127735925 C>T | 5'Flank (SNP) | VAF 20/30 reads (67%) | called by muse, varscan2
- MYC | c.-356C>T | 5'UTR (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331770 C>T | 5'Flank (SNP) | VAF 100/206 reads (49%) | called by muse, mutect2, varscan2
